Somatic mutation profile of tumor specimen CDDP-A8B9-TTP1-D (aliquot CDDP-A8B9-TTP1-D-1-0-D-A500-36) from CDDP_EAGLE case CDDP-A8B9, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 69 years.
Specimen CDDP-A8B9-TTP1-D: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd6e8694-7d64-4094-884a-cc89a589bea8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-A8B9-NB1-A (Blood Derived Normal), aliquot CDDP-A8B9-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a948cdb-28e2-4286-ba04-f609f20e23f1

The open-access MAF lists 51 somatic variants for this specimen: 34 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 11, Intron 3, RNA 3, Frame Shift Ins 1, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EDNRB | c.1027C>T p.R343* (on ENST00000377211 / NM_001201397.1; = p.R253* on NM_000115.5) | Nonsense Mutation (SNP) | VAF 38/350 reads (11%) | catalogued as rs104894390, CM993141, COSV57518833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 94/596 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 40/266 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BHLHA15 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552021360; called by muse, mutect2, varscan2
- CETN2 | c.264C>A p.D88E | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV64745658; called by muse, mutect2, varscan2
- CFAP46 | c.6304C>T p.L2102F | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs991048733; called by muse, mutect2
- EPB41 | c.1355G>A p.R452Q (on ENST00000343067 / NM_001166005.2; = p.R243Q on NM_004437.4) | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs146566071; called by muse, mutect2
- EZHIP | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 21/315 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.903); catalogued as rs1557318609, COSV100539867, COSV57954947, COSV57956805; called by muse, mutect2
- LRPAP1 | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs190769048; called by muse, mutect2, varscan2
- MACF1 | c.20632G>A p.V6878M (on ENST00000372915; = p.V4923M on NM_012090.5) | Missense Mutation (SNP) | VAF 25/151 reads (17%) | catalogued as rs1159902649; called by muse, mutect2, varscan2
- PLXNA3 | c.3373C>T p.P1125S | Missense Mutation (SNP) | VAF 67/340 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868915698; called by muse, mutect2, varscan2
- PXN | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs757350974, COSV57216920, COSV57220591; called by muse, mutect2, varscan2
- SPEM2 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.29); catalogued as rs369509500; called by muse, mutect2, varscan2
- ADGRG4 | c.4865del p.N1622Tfs*12 | Frame Shift Del (DEL) | VAF 20/189 reads (11%) | called by mutect2, pindel, varscan2
- BRF1 | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- CDHR2 | c.1954G>T p.A652S | Missense Mutation (SNP) | VAF 69/442 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- COL5A2 | c.1474G>T p.G492C | Missense Mutation (SNP) | VAF 39/330 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTTNBP2NL | c.1641C>G p.S547R | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CYBB | c.206T>G p.L69W | Missense Mutation (SNP) | VAF 45/437 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM71F1 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.037); called by muse, mutect2
- IQUB | c.2014G>C p.D672H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ITPR3 | c.408_434del p.N136_E144del | In Frame Del (DEL) | VAF 29/124 reads (23%) | called by mutect2, pindel
- NTN1 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- OR8B2 | c.862A>T p.I288F | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- RBBP8NL | c.8G>A p.S3N | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RHOD | c.62T>G p.V21G | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SACS | c.13559C>A p.T4520K | Missense Mutation (SNP) | VAF 61/261 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- SLITRK4 | c.1142A>C p.K381T | Missense Mutation (SNP) | VAF 33/354 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ST18 | c.2843T>G p.M948R | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TAGLN2 | c.376_380dup p.T128Sfs*4 | Frame Shift Ins (INS) | VAF 38/254 reads (15%) | called by mutect2, pindel, varscan2
- WLS | c.946A>G p.I316V | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- ZCCHC12 | c.137A>G p.K46R | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF655 | c.1339C>T p.H447Y | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF671 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRD9 | c.513T>C p.P171= | Silent (SNP) | VAF 33/112 reads (29%) | catalogued as rs928955983; called by muse, mutect2, varscan2
- DNAI4 | c.1227G>A p.R409= | Silent (SNP) | VAF 23/160 reads (14%) | catalogued as COSV64021461; called by muse, mutect2, varscan2
- HMCN1 | c.9C>T p.S3= | Silent (SNP) | VAF 74/439 reads (17%) | catalogued as rs372177834; called by muse, mutect2, varscan2
- KRAS | c.36T>A p.G12= | Silent (SNP) | VAF 39/264 reads (15%) | catalogued as COSV55510792, COSV55573999, COSV55588748; called by muse, mutect2, varscan2
- LINS1 | c.753T>C p.C251= | Silent (SNP) | VAF 35/192 reads (18%) | called by muse, mutect2, varscan2
- OR1M1 | c.576C>T p.T192= | Silent (SNP) | VAF 72/340 reads (21%) | catalogued as rs1568297301; called by muse, mutect2, varscan2
- OR2G3 | c.343T>C p.L115= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV100180692; called by muse, mutect2
- PLB1 | c.2793T>C p.V931= | Silent (SNP) | VAF 28/205 reads (14%) | called by muse, mutect2, varscan2
- PXN | c.66T>A p.P22= | Silent (SNP) | VAF 19/133 reads (14%) | called by muse, mutect2, varscan2
- SMTN | c.1539C>T p.N513= | Silent (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- SRFBP1 | c.687T>A p.T229= | Silent (SNP) | VAF 39/226 reads (17%) | called by muse, mutect2, varscan2
- C22orf34 | n.154G>A | RNA (SNP) | VAF 30/154 reads (19%) | called by muse, mutect2, varscan2
- CASP10 | c.685-3276del | Intron (DEL) | VAF 26/170 reads (15%) | called by mutect2, pindel, varscan2
- EAPP | c.74+178G>A | Intron (SNP) | VAF 58/284 reads (20%) | called by muse, mutect2, varscan2
- FASTKD3 | c.1700-30C>G | Intron (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- POM121L9P | n.952C>T | RNA (SNP) | VAF 61/596 reads (10%) | catalogued as rs1347002442; called by muse, mutect2, varscan2
- PRECSIT | n.679G>C | RNA (SNP) | VAF 45/218 reads (21%) | called by muse, mutect2, varscan2
